Somatic mutation profile of tumor specimen TARGET-10-PAPZNK-04A (aliquot TARGET-10-PAPZNK-04A-01D) from TARGET case TARGET-10-PAPZNK, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.0 years (3,658 days).
Specimen TARGET-10-PAPZNK-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bd9160c8-f07c-453b-88fc-8dba164f0fca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPZNK-10A (Blood Derived Normal), aliquot TARGET-10-PAPZNK-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5241fe2c-8553-47ac-837d-72fb48ffc3d1

The open-access MAF lists 43 somatic variants for this specimen: 32 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 9, RNA 1, Nonsense Mutation 1, Frame Shift Ins 1, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 113/303 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANKRD30B | c.2726C>T p.S909F | Missense Mutation (SNP) | VAF 139/638 reads (22%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.607); catalogued as COSV57704752; called by muse, varscan2
- C5AR2 | c.56G>A p.R19H | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as rs150108068, COSV57256464; called by muse, mutect2
- CCT7 | c.1232C>T p.A411V | Missense Mutation (SNP) | VAF 21/190 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54590550; called by mutect2, varscan2
- CD109 | c.4003G>A p.E1335K | Missense Mutation (SNP) | VAF 33/376 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.046); catalogued as COSV54658765; called by muse, mutect2
- CNOT1 | c.1868G>A p.R623Q | Missense Mutation (SNP) | VAF 17/236 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1011658922, COSV100410437, COSV57768261; called by muse, mutect2
- DPP3 | c.1957G>A p.E653K | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.278); catalogued as rs1462509737, COSV64757375; called by muse, mutect2, varscan2
- FNDC1 | c.5540C>T p.S1847F | Missense Mutation (SNP) | VAF 93/199 reads (47%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.889); catalogued as COSV51945002; called by muse, mutect2, varscan2
- GSE1 | c.2581G>A p.E861K | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as rs868139791, COSV53675254, COSV53677019; called by muse, mutect2, varscan2
- HELQ | c.1417C>T p.R473C | Missense Mutation (SNP) | VAF 21/342 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751377136, COSV55025334; called by muse, mutect2
- ITPR2 | c.7465G>A p.V2489M | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV67264302; called by muse, mutect2
- KDM5C | c.3401G>A p.G1134E | Missense Mutation (SNP) | VAF 64/71 reads (90%) | SIFT tolerated (0.44); PolyPhen benign (0.034); catalogued as COSV64771241; called by muse, mutect2, varscan2
- KPNB1 | c.973A>G p.I325V | Missense Mutation (SNP) | VAF 86/185 reads (46%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs773762133, COSV51601342; called by muse, mutect2, varscan2
- LAMA4 | c.182C>T p.P61L | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.003); catalogued as COSV54571631; called by mutect2, varscan2
- NBEAL1 | c.1078C>T p.R360* | Nonsense Mutation (SNP) | VAF 53/507 reads (10%) | catalogued as rs1173085860, COSV71375557; called by muse, mutect2, varscan2
- NT5C2 | c.1100G>A p.R367Q | Missense Mutation (SNP) | VAF 35/233 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.704); catalogued as rs1057519866, COSV58414509; ClinVar: not provided; called by muse, varscan2
- NT5C2 | c.1078T>C p.S360P | Missense Mutation (SNP) | VAF 76/230 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58420094; called by muse, varscan2
- OLFML2B | c.1355T>C p.V452A | Missense Mutation (SNP) | VAF 52/124 reads (42%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs1456669786, COSV54201357; called by muse, varscan2
- PCDHAC1 | c.1808C>T p.A603V | Missense Mutation (SNP) | VAF 73/143 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.616); catalogued as COSV53861906; called by muse, mutect2, varscan2
- PPP1R12A | c.1997G>A p.R666H | Missense Mutation (SNP) | VAF 31/222 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs771356750, COSV54105528; called by muse, mutect2, varscan2
- PRKDC | c.11621G>A p.R3874Q | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.195); catalogued as rs1177923241, COSV58067339; called by muse, mutect2, varscan2
- PRND | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.549); catalogued as COSV59897534; called by muse, mutect2, varscan2
- RBM26 | c.421C>G p.R141G | Missense Mutation (SNP) | VAF 51/112 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV57394497, COSV57401221; called by muse, mutect2, varscan2
- SETD3 | c.1281G>T p.W427C | Missense Mutation (SNP) | VAF 34/202 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.894); catalogued as COSV59287821; called by muse, mutect2, varscan2
- SPINK5 | c.2369G>A p.R790Q | Missense Mutation (SNP) | VAF 86/200 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs184189005, COSV56264325; called by muse, mutect2, varscan2
- TRPC3 | c.724C>T p.H242Y (on ENST00000379645 / NM_001366479.2; = p.H169Y on NM_003305.2) | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV53383224; called by muse, mutect2, varscan2
- UNC5D | c.664C>T p.R222W | Missense Mutation (SNP) | VAF 6/101 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1326693959; called by muse, mutect2
- UNC80 | c.758G>A p.R253Q | Missense Mutation (SNP) | VAF 72/177 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs547993640, COSV55884699; called by muse, mutect2, varscan2
- USH2A | c.11552G>A p.S3851N | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV56454757; called by muse, mutect2, varscan2
- ZAN | c.1348G>A p.V450M | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs1189246538, COSV61818649; called by muse, mutect2, varscan2
- DEPDC5 | c.1436_1444delinsGG p.T479Rfs*36 | Frame Shift Del (DEL) | VAF 31/112 reads (28%) | called by pindel, varscan2*
- WT1 | c.782dup p.E263* | Frame Shift Ins (INS) | VAF 24/78 reads (31%) | called by mutect2, pindel, varscan2
- ACKR3 | c.267C>T p.A89= | Silent (SNP) | VAF 56/164 reads (34%) | catalogued as rs147420191, COSV56023010; called by muse, mutect2, varscan2
- FPR2 | c.906C>T p.Y302= | Silent (SNP) | VAF 14/164 reads (9%) | catalogued as rs143928920; called by muse, mutect2
- GABRB3 | c.1407G>A p.L469= | Silent (SNP) | VAF 29/75 reads (39%) | catalogued as rs776346710, COSV54688698; called by muse, mutect2, varscan2
- MRPL45 | c.312A>T p.G104= | Silent (SNP) | VAF 93/244 reads (38%) | called by muse, mutect2, varscan2
- PCDH15 | c.1245G>A p.S415= | Silent (SNP) | VAF 69/201 reads (34%) | catalogued as rs775789634, COSV57314845; ClinVar: likely benign; called by muse, mutect2, varscan2
- POLD1 | c.2292C>T p.G764= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as rs146960286; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYT10 | c.177C>T p.V59= | Silent (SNP) | VAF 16/131 reads (12%) | catalogued as rs772937480, COSV57337876; called by muse, mutect2, varscan2
- TEP1 | c.1635C>T p.L545= | Silent (SNP) | VAF 14/140 reads (10%) | catalogued as COSV53002205; called by muse, mutect2, varscan2
- USP24 | c.4062A>T p.P1354= | Silent (SNP) | VAF 14/124 reads (11%) | catalogued as COSV53781144; called by muse, mutect2, varscan2
- ANAPC1P5 | n.479T>A | RNA (SNP) | VAF 62/498 reads (12%) | called by muse, mutect2, varscan2
- OR9G4 | chr11:56741066 G>A | 3'Flank (SNP) | VAF 62/199 reads (31%) | catalogued as rs375905839; called by muse, mutect2, varscan2
